Gene-level copy-number profile of tumor specimen ALCH-AEQJ-TTP1-A from ALCHEMIST case ALCH-AEQJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.7 years (24,349 days).
Specimen ALCH-AEQJ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c0666229-f674-4ef0-97ca-00fa11340ea9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEQJ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,239 have no estimate.
https://portal.gdc.cancer.gov/files/92d9d36c-921f-441f-8e94-c1012b5fb751

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 108; copy number 1: 6,905; copy number 2: 50,027; copy number 3: 1,297; copy number 4: 31; copy number 5: 10; copy number 7: 1; copy number 9: 1; copy number 12: 1; copy number 16: 1; copy number 29: 2.

Homozygous deletions (total copy number 0; autosomes only): 108 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:232,539,692–232,548,115, 1 gene (within-gene range 0–2): CHRNG.
- chr2:240,435,663–240,468,076, 3 genes: GPC1, AC110619.1, MIR149.
- chr3:48,636,463–48,662,886, 2 genes: CELSR3, MIR4793.
- chr3:52,316,319–52,535,054, 9 genes (within-gene range 0–2): DNAH1, PPP2R5CP, BAP1, PHF7, SEMA3G, TNNC1, NISCH, STAB1, NT5DC2.
- chr5:1,050,384–1,112,063, 2 genes: SLC12A7, MIR4635.
- chr7:45,080,437–45,088,969, 1 gene: NACAD.
- chr7:56,525,428–56,538,676, 2 genes: AC092447.3, AC092447.5.
- chr9:130,902,438–130,945,520, 2 genes: FIBCD1, AL161733.1.
- chr9:134,317,098–134,440,585, 2 genes: RXRA, MIR4669.
- chr9:137,168,758–137,190,370, 6 genes (within-gene range 0–2): LRRC26, AL929554.1, MIR3621, TMEM210, ANAPC2, SSNA1.
- chr10:42,979,017–43,138,334, 4 genes: LINC01264, MIR5100, RET, AC010864.1.
- chr11:17,435,672–17,436,181, 1 gene (within-gene range 0–1): SDHCP4.
- chr11:61,746,493–61,757,655, 1 gene (within-gene range 0–2): MYRF-AS1.
- chr15:25,169,337–25,257,027, 46 genes (within-gene range 0–2): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44, AC124303.1.
- chr16:68,367,325–68,370,262, 1 gene (within-gene range 0–2): AC099521.2.
- chr18:79,420,836–79,422,780, 1 gene (within-gene range 0–1): AC018445.3.
- chr19:2,163,933–2,232,578, 2 genes (within-gene range 0–2): DOT1L, AC004490.1.
- chr19:4,969,113–5,153,598, 1 gene: KDM4B.
- chr19:44,882,027–44,890,876, 1 gene (within-gene range 0–2): AC011481.2.
- chr20:63,939,829–63,956,416, 3 genes (within-gene range 0–1): UCKL1, MIR1914, MIR647.
- chr21:46,098,112–46,132,848, 1 gene: COL6A2.
- chr22:20,198,729–20,283,246, 4 genes: AC007663.2, LINC00896, RTN4R, MIR1286.
- chr22:21,652,270–21,700,015, 9 genes (within-gene range 0–2): AP000553.1, MIR301B, MIR130B, AP000553.5, AP000553.6, AP000553.7, AP000553.4, AP000553.2, PPIL2.
- chr22:29,720,003–29,731,833, 1 gene (within-gene range 0–2): CABP7.
- chr22:45,875,999–45,977,162, 2 genes (within-gene range 0–1): BX324167.1, WNT7B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 16 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,906,757–89,916,052, 2 genes, copy number 5: IGKV3D-34, IGKV1D-33.
- chr11:65,487,241–65,538,704, 8 genes, copy number 5 (within-gene range 2–5): LINC02736, AP000769.6, MALAT1, AP000769.2, AP000769.5, AP000769.3, SNRPGP19, SCYL1.
- chr14:104,800,596–104,804,712, 1 gene, copy number 9: ZBTB42.
- chr21:44,107,373–44,210,114, 2 genes, copy number 7–12 (within-gene range 3–29): PWP2, GATD3A.
- chr21:44,172,169–44,194,338, 2 genes, copy number 29: AP001056.2, AP001056.1.
- chr22:21,125,660–21,128,063, 1 gene, copy number 16: POM121L7P.

Autosomal genes at a single copy (total copy number 1): 6,773. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
